Somatic mutation profile of tumor specimen TARGET-20-PAMYAS-04A (aliquot TARGET-20-PAMYAS-04A-02D) from TARGET case TARGET-20-PAMYAS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.9 years (3,972 days).
Specimen TARGET-20-PAMYAS-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87543a5c-7b00-414f-94a6-d9703a00bfff.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAMYAS-14A (Bone Marrow Normal), aliquot TARGET-20-PAMYAS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42050ada-5933-4373-a2e9-1c37384dd822

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TET2 | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | hotspot (GDC flag); catalogued as rs572712965, COSV54395664; called by muse, mutect2, varscan2
- CARD11 | c.2808C>T p.D936= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs375569843; called by muse, mutect2, varscan2
